Surgical pathology report (de-identified scan), TCGA case TCGA-F7-8298, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site Asterand, specimen TCGA-F7-8298-01A (Primary Tumor).

[page 1 of 5]
[Redacted]

[Redacted]

		Case ID	Gross Description

[page 2 of 5]
Microscopic Description	Diagnosis Details

[page 3 of 5]
Comments	Formatted Path Report
	LARYNX TISSUE CHECKLIST Specimen type: Laryngectomy Tumor site: Glottis Tumor size: 4 x 4 x 2 cm Histologic type: Squamous cell carcinoma Histologic grade: Well differentiated Tumor extent: Vocal cord Lymph nodes: 0/14 positive for metastasis (Regional 0/14) Margins: Not specified Evidence of neo-adjuvant treatment: Not specified Comments: None

[page 4 of 5]
Laterality		ID

[page 5 of 5]
Excision date				Case ID

Source: NCI Genomic Data Commons file f4c6690e-4ff8-4ac3-95d6-f8c2647a2581 (TCGA-F7-8298.5E3145E1-5889-4DB6-918D-DC4E02B7D11D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).